Surgical pathology report (de-identified scan), TCGA case TCGA-3S-A8YW, project TCGA-THYM (Thymoma), tissue source site University of New Mexico, specimen TCGA-3S-A8YW-01A (Primary Tumor).

[page 1 of 4]
Result type: Surgical Pathology Final Report
Result date: [REDACTED]
Result status: Auth (Verified)
Result title: Surgical Procedure
Performed by: [REDACTED]
Verified by: [REDACTED]
Encounter info: [REDACTED]
Contributor system: [REDACTED]

* Final Report *

Surgical Procedure

CASE: [REDACTED]

PATIENT: [REDACTED]

SPECIMENS SUBMITTED:

- A. THYMIC MASS
- B. HILAR NODE

DIAGNOSIS:

A. MEDIASTINUM, THYMUS; THYMECTOMY:

- THYMIC CARCINOMA
- HISTOLOGIC TYPE: SQUAMOUS CELL CARCINOMA
- TUMOR SIZE: 7 cm
- TUMOR INVASION
- TUMOR CAPSULE/MEDIASTINAL FAT: POSITIVE, TUMOR INVADES

PERICAPSULAR CONNECTIVE TISSUE (BEST SEEN IN BLOCK A4)

- PLEURA/PERICARDIUM: NEGATIVE
- LUNG PARENCHYMA: NOT PRESENT FOR EVALUATION
- DIAPHRAGM: NOT PRESENT FOR EVALUATION
- LYMPH-VASCULAR INVASION: NEGATIVE
- IMPLANTS/DISTANT METASTASIS: NOT PRESENT FOR

EVALUATION

- SPECIMEN CHARACTERISTICS
- SPECIMEN INTEGRITY: INTACT

ICD O 3
c64f
Thymoma, type C 8586/3
path
Carcinoma, squamous cell NOS
8574/3
Site: Thymus C879
JES 3/11/14

[page 2 of 4]
- MARGINS: NEGATIVE
- TREATMENT EFFECT: NOT APPLICABLE
- REGIONAL LYMPH NODES
- HILAR NODES: 0 OF 6 LYMPH NODES POSITIVE FOR METASTATIC TUMOR (0/6)
- MEDIASTINAL FAT: 0 OF 1 LYMPH NODE POSTIVE FOR METASTATIC TUMOR (0/1)
- OTHER FINDINGS
- MULTIPLE SUB-MILLIMETER BENIGN MICROSCOPIC THYOMAS (BLOCK A9)
- RESIDUAL THYMUS WITH INVOLUTIONAL CHANGES
- PATHOLOGIC STAGE: T2N0

COMMENT: The tumor shows nests and cords of neoplastic cells with squamoid cytoplasm and high-grade nuclear features including macronucleoli, frequent mitoses, and necrosis, separated by dense bands of fibrosis. Appropriately controlled immunohistochemical stains performed at [REDACTED] [REDACTED] show positive staining for pancytokeratin, p40, CD5, and CD117 (c-kit), only weak focal staining for synaptophysin, and negative staining for chromogranin, TTF-1, and napsin. These findings are consistent with a primary thymic carcinoma of the squamous cell type (of note, squamous cell carcinoma is the most common subtype of thymic carcinoma). Incidentally noted are two benign, submillimeter microscopic thymomas present in the residual involuted thymic tissue. This case was reviewed at the [REDACTED] on [REDACTED], and separately by [REDACTED]

CLINICAL INFORMATION: [REDACTED] with history of thymoma.

GROSS DESCRIPTION: Number of specimen containers: 1. Labeled with patient name: [REDACTED] and MRN [REDACTED].

A. Container designation: "thymic mass" -- Received fresh is a 7 x 7 x 4.5 cm ovoid mass with a nodular anterior surface that is light tan. The

[page 3 of 4]
deep portion of the specimen is bonded by a smooth pericardium that is grossly free of lesion. Attached to the infero-lateral aspect of the specimen is an 11.5 x 25 x 2 cm portion of lobulated yellow fibromembranous tissue. The superficial surface of the mass is inked in black by the surgeon, the superior aspect is inked green, and the deep surface of the attached smooth pericardium is inked in red. The mass is serially sectioned and demonstrates a smooth pink-tan lobulated cut surface with minute white fibrous septations coursing through the lesion. The lesion appears to be multifocal with a 1.5 x 1 cm area that is bounded by yellow lobulated tissue within the larger mass. The mass grossly abuts the inked superficial and superior margin, and is grossly within 1 mm of the deep margin, and grossly 2 mm from the inferior margin which is inked in blue.

The attached fat is serially sectioned revealing yellow lobulated fibromembranous material without any discrete lesions. Cassette summary: submitted in cassette A1 - lesion to closest superficial margin; A2 - lesion closest to nearest deep margin; A3 - lesion closest to nearest superior margin; A4 - lesion closest to nearest superior margin; A5 - lesion closest to nearest inferior margin; A6 - lesion with adjacent fat at inferior margin; A7 - representative sections of the lateral aspects of the superficial margin; A8 - representative sections of the deep margin; A9 - representative sections of grossly uninvolved fat that is adjacent to mass; A10 - A12 - representative sections from the attached portion of adipose tissue.

B. Container designation: "Hilar node" - Received unfixed are four fragments of tan-pink brown-black soft tissue that range in size from 0.2 to 1.5 cm in greatest dimension. The specimen is entirely submitted in cassette B1.

(Dictated by: [REDACTED])

MICROSCOPIC DESCRIPTION: Histologic examination performed.

Any tests performed using Analytic Specific Reagents (ASR) were developed and validated by [REDACTED]. The U.S. Food and Drug

[page 4 of 4]
Administration has not approved these tests but has determined that such clearance or approval is not necessary. These tests should be regarded as a clinical assay for standard medical care.

The [REDACTED] was present during the formal review and interpretation of all slides and ancillary studies, (if performed), with the [REDACTED]. Specimens with only gross examination were reviewed and interpreted by the [REDACTED].

[REDACTED]

HIFAA Discrepancy		✓

Source: NCI Genomic Data Commons file a60c583e-3348-4453-a7c8-8638ef860389 (TCGA-3S-A8YW.F59BF4F4-ED39-45DD-AD20-FC3BDD08F73A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).